Somatic mutation profile of tumor specimen TCGA-B6-A0RE-01A (aliquot TCGA-B6-A0RE-01A-11W-A071-09) from TCGA case TCGA-B6-A0RE, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage X; Age at diagnosis: 61.5 years (22,449 days).
Specimen TCGA-B6-A0RE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 61dc82f9-39aa-45b5-9be6-4f31fe2ce39b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B6-A0RE-10A (Blood Derived Normal), aliquot TCGA-B6-A0RE-10A-01W-A071-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cf993d8f-566e-48e0-a6de-b70c0d40fc79

The open-access MAF lists 161 somatic variants for this specimen: 126 protein-altering or splice-affecting, 34 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 104, Silent 34, Nonsense Mutation 10, In Frame Del 3, Splice Region 3, Frame Shift Del 2, Frame Shift Ins 2, RNA 1, Nonstop Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.1607A>G p.N536S | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as COSV70033151; called by muse, mutect2, varscan2
- ABCF2 | c.1346C>A p.P449H | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55184103; called by muse, mutect2, varscan2
- AC008397.2 | c.1780G>C p.E594Q | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53207916; called by muse, mutect2, varscan2
- ACCS | c.1186C>T p.L396F | Missense Mutation (SNP) | VAF 73/267 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55459023; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.062); catalogued as rs113761300, COSV58447065; called by muse, mutect2
- ADGRB1 | c.2371T>G p.W791G | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.596); catalogued as COSV60099176; called by muse, mutect2, varscan2
- ADPGK | c.889G>C p.E297Q | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as COSV100295122; called by muse, mutect2
- AHCTF1 | c.2656A>G p.M886V (on ENST00000366508; = p.M860V on NM_015446.5) | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.487); catalogued as COSV100403049; called by muse, mutect2
- ALDH1L1 | c.198G>C p.L66F | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV56415852; called by muse, mutect2, varscan2
- AMPD3 | c.826C>T p.R276W (on ENST00000396553 / NM_001025389.2; = p.R285W on NM_000480.3) | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs745918146, COSV67331478; called by muse, mutect2, varscan2
- APOB | c.3112C>T p.Q1038* | Nonsense Mutation (SNP) | VAF 129/271 reads (48%) | catalogued as rs1283424766, COSV51935785; called by muse, mutect2, varscan2
- APP | c.124A>C p.N42H | Missense Mutation (SNP) | VAF 21/438 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100695215; called by muse, mutect2
- ARHGAP21 | c.4558C>T p.R1520C | Missense Mutation (SNP) | VAF 49/882 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1309575983, COSV100255689; called by muse, mutect2
- ARHGEF11 | c.874A>G p.I292V | Missense Mutation (SNP) | VAF 14/286 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.72); catalogued as rs1470642015, COSV100809621; called by muse, mutect2
- ARID4A | c.3109C>G p.Q1037E | Missense Mutation (SNP) | VAF 96/171 reads (56%) | SIFT tolerated (0.11); PolyPhen benign (0.107); catalogued as COSV62164787; called by muse, mutect2, varscan2
- ARMC4 | c.388A>G p.R130G | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV53466283; called by muse, mutect2
- ASB15 | c.159A>G p.Q53= | Splice Region (SNP) | VAF 77/143 reads (54%) | catalogued as COSV51927049; called by muse, mutect2, varscan2
- ATMIN | c.395G>T p.C132F | Missense Mutation (SNP) | VAF 9/259 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100214496; called by muse, mutect2
- BAZ1A | c.2362G>A p.E788K | Missense Mutation (SNP) | VAF 78/145 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV62410820; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1786G>C p.D596H | Missense Mutation (SNP) | VAF 62/269 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100863738, COSV63245642; called by muse, mutect2, varscan2
- BMPR2 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV65810730; called by muse, mutect2
- BNIP3L | c.402G>T p.L134F | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV66078215, COSV99073611; called by muse, mutect2, varscan2
- BNIP3L | c.403A>G p.K135E | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as rs762423471, COSV66078218; called by muse, mutect2, varscan2
- BRDT | c.180A>T p.K60N | Missense Mutation (SNP) | VAF 52/260 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.91); catalogued as COSV61771291; called by muse, mutect2
- CCDC180 | c.415A>C p.S139R | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs17855671, COSV63831794; called by muse, mutect2, varscan2
- CCHCR1 | c.1064A>G p.H355R | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.73); catalogued as COSV66184150; called by muse, mutect2, varscan2
- CDH19 | c.1372G>C p.V458L | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV50963880; called by muse, mutect2, varscan2
- CDH9 | c.2292T>A p.Y764* | Nonsense Mutation (SNP) | VAF 43/588 reads (7%) | catalogued as COSV50318199, COSV99152079; called by muse, mutect2
- CENPF | c.6587G>A p.R2196K | Missense Mutation (SNP) | VAF 153/419 reads (37%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV65276195; called by muse, mutect2, varscan2
- CHD3 | c.3562G>A p.A1188T | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs1314577386, COSV100390608, COSV100391172; called by muse, mutect2
- CHST5 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs761010831, COSV60340105; called by muse, mutect2
- CKAP2 | c.1486G>T p.E496* (on ENST00000378037 / NM_001098525.2; = p.E495* on NM_018204.5) | Nonsense Mutation (SNP) | VAF 5/58 reads (9%) | catalogued as COSV51622992; called by muse, mutect2
- CRYBG3 | c.6995T>C p.V2332A | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV51713347; called by muse, mutect2, varscan2
- DNAH11 | c.1204T>A p.Y402N | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.409); catalogued as COSV60963859; called by muse, mutect2
- DNAH9 | c.8169G>T p.K2723N | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as rs1470476711, COSV52357848; called by muse, mutect2
- EHD2 | c.666C>G p.D222E | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV54409416; called by muse, mutect2, varscan2
- EPS8L1 | c.2171G>C p.*724Sext*24 (on ENST00000201647 / NM_133180.3; = p.*597Sext*24 on NM_017729.3) | Nonstop Mutation (SNP) | VAF 10/51 reads (20%) | catalogued as COSV52383410, COSV52383580; called by muse, mutect2, varscan2
- FANCD2 | c.2192C>T p.A731V | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.763); catalogued as COSV55041036; called by muse, mutect2, varscan2
- FZD3 | c.1606C>A p.L536I | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.632); catalogued as COSV53536357; called by muse, mutect2, varscan2
- GABRR3 | c.348C>G p.D116E | Missense Mutation (SNP) | VAF 57/131 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV72084168; called by muse, mutect2, varscan2
- GAS6 | c.449dup p.R151Pfs*27 | Frame Shift Ins (INS) | VAF 7/20 reads (35%) | catalogued as rs773341392; called by mutect2, varscan2
- GLA | c.277G>C p.D93H | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM051063, CM118192, COSV54509739; called by muse, mutect2, varscan2
- GNPNAT1 | c.130C>G p.L44V | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53591393; called by muse, mutect2, varscan2
- GPRASP2 | c.1019T>G p.V340G | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV100176513; called by muse, mutect2, varscan2
- GUCY1B1 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as COSV52375814, COSV52376598, COSV52377523; called by muse, mutect2
- HEMGN | c.1413G>C p.E471D | Missense Mutation (SNP) | VAF 51/75 reads (68%) | SIFT tolerated (0.07); PolyPhen benign (0.139); catalogued as rs751804933, COSV52326786; called by muse, mutect2, varscan2
- HPDL | c.888G>C p.Q296H | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV58344468; called by muse, mutect2, varscan2
- IFT122 | c.2720C>G p.A907G (on ENST00000348417 / NM_052989.3; = p.A848G on NM_018262.4) | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.075); catalogued as COSV56204728; called by muse, mutect2, varscan2
- INTS3 | c.2131G>C p.A711P | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100015584; called by muse, mutect2
- IP6K3 | c.630T>A p.H210Q | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as rs139534699, COSV53388862; called by muse, mutect2, varscan2
- ITPRID1 | c.2764G>T p.A922S | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.23); catalogued as COSV100085547; called by muse, mutect2
- KCNA5 | c.1255G>T p.G419W | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52906973; called by muse, mutect2, varscan2
- KRT222 | c.430G>C p.E144Q | Missense Mutation (SNP) | VAF 145/234 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67498171, COSV67498509; called by muse, mutect2, varscan2
- LAMA4 | c.5108G>T p.G1703V (on ENST00000230538 / NM_001105206.3; = p.G1696V on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/516 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57899845; called by muse, mutect2, varscan2
- LAPTM4B | c.440C>G p.S147* (on ENST00000445593; = p.S56* on NM_018407.6) | Nonsense Mutation (SNP) | VAF 35/159 reads (22%) | catalogued as COSV71454384; called by muse, mutect2, varscan2
- LCP1 | c.1831A>T p.M611L | Missense Mutation (SNP) | VAF 30/207 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV59941767; called by muse, mutect2, varscan2
- LRIF1 | c.1699G>C p.D567H | Missense Mutation (SNP) | VAF 41/322 reads (13%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.943); catalogued as COSV63897771; called by muse, mutect2, varscan2
- LTBP1 | c.3959A>G p.Y1320C (on ENST00000404816 / NM_206943.4; = p.Y994C on NM_000627.4) | Missense Mutation (SNP) | VAF 14/191 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748096563, COSV55380142, COSV99697671; called by muse, mutect2
- MAGED1 | c.192C>A p.D64E | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100431351; called by muse, mutect2
- MAPT | c.261C>G p.D87E (on ENST00000262410 / NM_001377265.1; = p.D116E on NM_005910.5) | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.411); catalogued as COSV52242328, COSV99291071; called by muse, mutect2
- MDN1 | c.6953C>A p.A2318E | Missense Mutation (SNP) | VAF 24/288 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV65524148; called by muse, mutect2
- MTARC1 | c.813C>T p.S271= | Splice Region (SNP) | VAF 5/98 reads (5%) | catalogued as COSV65056047; called by muse, mutect2
- MUC16 | c.22585A>T p.T7529S | Missense Mutation (SNP) | VAF 42/504 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.07); catalogued as COSV67476070; called by muse, mutect2
- MYB | c.1212C>G p.N404K | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as COSV57199340; called by muse, mutect2, varscan2
- MYO5B | c.1214C>T p.A405V | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs745968678, COSV53220794; called by muse, mutect2, varscan2
- NLRP5 | c.3214C>A p.L1072I | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV66765650; called by muse, mutect2, varscan2
- NUP210 | c.3687G>A p.A1229= | Splice Region (SNP) | VAF 6/23 reads (26%) | catalogued as rs770494503, COSV54408566; called by muse, mutect2
- OR10V1 | c.285C>G p.I95M | Missense Mutation (SNP) | VAF 47/202 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as COSV55699012; called by muse, mutect2, varscan2
- PCDHA8 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.608); catalogued as COSV100970403, COSV65334844; called by muse, mutect2
- PGLYRP3 | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 107/415 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51951129; called by muse, mutect2, varscan2
- PIAS4 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs111928159, COSV53679800; called by muse, mutect2, varscan2
- PIK3C2G | c.3231T>G p.N1077K (on ENST00000676171; = p.N1036K on NM_004570.5) | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56815864; called by muse, mutect2
- PIWIL1 | c.1845G>T p.E615D | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV99805949; called by muse, mutect2
- PPME1 | c.341G>A p.S114N | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as rs780960664, COSV60296954; called by muse, mutect2
- PPP2R2B | c.188G>A p.R63H (on ENST00000394409; = p.R129H on NM_181674.2) | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs775290828, COSV100353224; called by muse, mutect2, varscan2
- PRDM7 | c.1046C>A p.P349Q | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV100371029; called by muse, mutect2
- PRTG | c.324A>T p.E108D | Missense Mutation (SNP) | VAF 99/295 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.952); catalogued as COSV66838834; called by muse, mutect2, varscan2
- PTGES3 | c.215C>A p.S72* | Nonsense Mutation (SNP) | VAF 6/64 reads (9%) | catalogued as COSV100009550; called by muse, mutect2
- PTPRD | c.4869A>C p.R1623S | Missense Mutation (SNP) | VAF 51/800 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as COSV61958696; called by muse, mutect2
- R3HDM1 | c.2272C>T p.Q758* | Nonsense Mutation (SNP) | VAF 12/198 reads (6%) | catalogued as COSV99925609; called by muse, mutect2
- RAP2B | c.245A>G p.Y82C | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV60256778, COSV60257178; called by muse, mutect2, varscan2
- RBPJL | c.758-2A>T p.X253_splice | Splice Site (SNP) | VAF 32/171 reads (19%) | catalogued as COSV100643425; called by muse, mutect2, varscan2
- RP1 | c.873C>A p.D291E | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV55119969; called by muse, mutect2, varscan2
- RPL4 | c.535G>C p.D179H | Missense Mutation (SNP) | VAF 63/110 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57181224; called by muse, mutect2, varscan2
- RSPH9 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 132/331 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.095); catalogued as COSV64665273; called by muse, mutect2, varscan2
- SCN11A | c.3964G>A p.D1322N | Missense Mutation (SNP) | VAF 12/191 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1011224550, COSV56572882; called by muse, mutect2
- SEC14L5 | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.244); catalogued as rs771856728, COSV52039565; called by muse, mutect2, varscan2
- SEMA3D | c.566A>T p.Q189L | Missense Mutation (SNP) | VAF 24/260 reads (9%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.741); catalogued as COSV52397190; called by muse, mutect2
- SLC13A1 | c.1450T>A p.L484I | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.207); catalogued as COSV52013400; called by muse, mutect2, varscan2
- SLC2A3 | c.1067A>G p.K356R | Missense Mutation (SNP) | VAF 64/357 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.405); catalogued as COSV50004260; called by muse, mutect2, varscan2
- SLC44A5 | c.1223C>T p.P408L | Missense Mutation (SNP) | VAF 19/194 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV100900957; called by muse, mutect2, varscan2
- SLCO2A1 | c.1502C>A p.S501* | Nonsense Mutation (SNP) | VAF 28/51 reads (55%) | catalogued as rs755103592, COSV60486933; called by muse, mutect2, varscan2
- SLCO2A1 | c.991G>C p.V331L | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.014); catalogued as COSV60486942; called by muse, mutect2, varscan2
- SPIDR | c.1955C>G p.T652R | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99854121; called by muse, mutect2
- SPTBN4 | c.7417C>G p.P2473A | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.178); catalogued as COSV52541098; called by muse, mutect2
- STK10 | c.1057A>T p.N353Y | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as COSV51575742; called by muse, mutect2, varscan2
- SULT1C3 | c.876G>C p.K292N | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.341); catalogued as COSV61253490, COSV61254203; called by muse, mutect2
- SWT1 | c.140C>A p.S47* | Nonsense Mutation (SNP) | VAF 32/230 reads (14%) | catalogued as COSV62256536; called by muse, mutect2, varscan2
- SWT1 | c.1301A>T p.K434M | Missense Mutation (SNP) | VAF 41/397 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV62256543; called by muse, mutect2, varscan2
- TGFB3 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.615); catalogued as COSV53170378; called by muse, mutect2, varscan2
- TMOD1 | c.85A>C p.T29P | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as COSV52249280; called by muse, varscan2
- TMOD1 | c.86C>G p.T29S | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV52249292; called by muse, varscan2
- TP53 | c.907del p.S303Afs*42 | Frame Shift Del (DEL) | VAF 53/113 reads (47%) | catalogued as COSV52729387, COSV53200423; called by mutect2, pindel, varscan2
- TRIM67 | c.1847C>G p.S616C | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as rs1029022619, COSV64158411, COSV64159207; called by muse, mutect2, varscan2
- TRIR | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV54407215; called by muse, mutect2, varscan2
- TRPV6 | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1466949494; called by muse, mutect2
- TSPEAR | c.850C>A p.Q284K | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as rs1253757058, COSV59968111; called by mutect2, varscan2
- UBA7 | c.2445C>A p.N815K | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60967949; called by muse, mutect2, varscan2
- UNC5D | c.1892G>A p.W631* | Nonsense Mutation (SNP) | VAF 11/181 reads (6%) | catalogued as COSV54787972; called by muse, mutect2
- USH2A | c.9971G>T p.C3324F | Missense Mutation (SNP) | VAF 30/384 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56391789; called by muse, mutect2
- UTRN | c.5281G>T p.V1761F | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.121); catalogued as COSV62339636; called by muse, mutect2, varscan2
- VPS8 | c.1205A>G p.Y402C (on ENST00000625842 / NM_001349294.1; = p.Y400C on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as rs1186539253, COSV54989455; called by muse, mutect2, varscan2
- WNT8B | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1428736297, COSV59325856, COSV59327040; called by muse, mutect2, varscan2
- ZC3HC1 | c.1051C>T p.R351* | Nonsense Mutation (SNP) | VAF 32/100 reads (32%) | catalogued as rs777405892, COSV61298936; called by muse, varscan2
- ZFP37 | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.305); catalogued as COSV65287567, COSV65288073; called by muse, mutect2, varscan2
- ZKSCAN4 | c.303C>G p.F101L | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as COSV101043344; called by muse, mutect2
- ZNF224 | c.905G>C p.R302T | Missense Mutation (SNP) | VAF 28/307 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.215); catalogued as COSV61242673; called by muse, mutect2
- ZNF526 | c.1615C>G p.Q539E | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as COSV55899836; called by muse, mutect2, varscan2
- ZNF619 | c.970G>C p.G324R | Missense Mutation (SNP) | VAF 22/241 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV59030434; called by muse, mutect2
- ZRANB3 | c.1771G>C p.E591Q | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV99922483; called by muse, mutect2
- ZWINT | c.773A>G p.D258G | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.217); catalogued as COSV100571475; called by muse, mutect2, varscan2
- ADAM15 | c.1225_1227del p.C409del | In Frame Del (DEL) | VAF 5/33 reads (15%) | called by mutect2, pindel, varscan2
- BCKDK | c.655_657del p.G219del | In Frame Del (DEL) | VAF 3/29 reads (10%) | called by mutect2, pindel
- BLK | c.23dup p.P9Afs*46 | Frame Shift Ins (INS) | VAF 10/51 reads (20%) | called by mutect2, pindel, varscan2
- NOTCH2 | c.6890del p.P2297Lfs*9 | Frame Shift Del (DEL) | VAF 60/134 reads (45%) | called by mutect2, pindel, varscan2
- PLK2 | c.2043_2051delinsTCA p.L681_C684delinsFH | In Frame Del (DEL) | VAF 27/80 reads (34%) | called by pindel, varscan2*
- ADAMTS17 | c.906G>T p.R302= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV51485057; called by muse, mutect2, varscan2
- ADCY2 | c.3219G>A p.T1073= | Silent (SNP) | VAF 14/182 reads (8%) | catalogued as rs570658451, COSV57881208; called by muse, mutect2
- ADGRL2 | c.4068A>G p.T1356= (on ENST00000370717 / NM_001366005.1; = p.T1300= on NM_012302.4) | Silent (SNP) | VAF 17/176 reads (10%) | catalogued as rs1459678806, COSV99586940; called by muse, mutect2
- AFF2 | c.2283T>C p.S761= | Silent (SNP) | VAF 43/189 reads (23%) | catalogued as COSV53995436; called by muse, mutect2, varscan2
- ALAS1 | c.906G>C p.G302= | Silent (SNP) | VAF 37/140 reads (26%) | catalogued as COSV59628454; called by muse, mutect2, varscan2
- APOH | c.27C>T p.F9= | Silent (SNP) | VAF 8/138 reads (6%) | catalogued as COSV52773409; called by muse, mutect2
- C4BPB | c.36G>C p.A12= | Silent (SNP) | VAF 12/134 reads (9%) | catalogued as rs188656684, COSV54691871; called by muse, mutect2
- CARD17 | c.66A>T p.I22= | Silent (SNP) | VAF 90/942 reads (10%) | catalogued as COSV65215211; called by muse, mutect2
- CBL | c.561G>A p.A187= | Silent (SNP) | VAF 59/268 reads (22%) | catalogued as rs1272874156, COSV50644078; called by muse, mutect2, varscan2
- CCDC138 | c.309G>A p.Q103= | Silent (SNP) | VAF 36/163 reads (22%) | catalogued as COSV54568704; called by muse, mutect2
- CENPO | c.72A>G p.L24= | Silent (SNP) | VAF 20/256 reads (8%) | catalogued as COSV99578758; called by muse, mutect2
- COG7 | c.2100C>T p.I700= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs1484774663, COSV56152438; called by muse, mutect2, varscan2
- CYP26A1 | c.768C>T p.C256= | Silent (SNP) | VAF 22/27 reads (81%) | catalogued as COSV56418911; called by muse, mutect2, varscan2
- CYP4A11 | c.54C>A p.I18= | Silent (SNP) | VAF 18/180 reads (10%) | catalogued as COSV60224212; called by muse, mutect2, varscan2
- DHX9 | c.840A>G p.Q280= | Silent (SNP) | VAF 18/296 reads (6%) | catalogued as COSV100841222; called by muse, mutect2
- DOT1L | c.2712G>T p.V904= | Silent (SNP) | VAF 4/7 reads (57%) | catalogued as rs1386771329, COSV67110906; called by mutect2, varscan2
- DPEP3 | c.1212C>G p.V404= | Silent (SNP) | VAF 66/92 reads (72%) | catalogued as COSV52051776, COSV99262651; called by muse, mutect2, varscan2
- FCAR | c.630C>G p.A210= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV62030289; called by muse, mutect2, varscan2
- HECW1 | c.3888G>A p.S1296= | Silent (SNP) | VAF 32/229 reads (14%) | catalogued as rs764833849, COSV67832225; called by muse, mutect2, varscan2
- IFNAR2 | c.108T>C p.D36= | Silent (SNP) | VAF 12/189 reads (6%) | catalogued as rs1306309401, COSV100577061; called by muse, mutect2
- ITIH2 | c.279A>G p.K93= | Silent (SNP) | VAF 60/550 reads (11%) | catalogued as COSV100623130; called by muse, mutect2, varscan2
- KLK5 | c.411C>G p.V137= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as rs111743221, COSV60450718; called by mutect2, varscan2
- LAMP2 | c.1116C>T p.D372= | Silent (SNP) | VAF 79/260 reads (30%) | catalogued as rs749338632, COSV52351527; ClinVar: likely benign; called by muse, mutect2, varscan2
- LARS1 | c.726G>A p.P242= (on ENST00000394434 / NM_020117.11; = p.P215= on NM_016460.3) | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as rs777918410, COSV50979559; ClinVar: likely benign; called by muse, mutect2, varscan2
- MCM4 | c.2307G>A p.L769= | Silent (SNP) | VAF 35/194 reads (18%) | catalogued as rs1441663131, COSV50625724; called by muse, mutect2, varscan2
- PSMD3 | c.279C>T p.F93= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs201112076, COSV52858402; called by muse, mutect2, varscan2
- PTPN2 | c.1137A>G p.R379= | Silent (SNP) | VAF 12/244 reads (5%) | catalogued as COSV58997609; called by muse, mutect2
- RSPH6A | c.1365C>T p.I455= | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as COSV99679527; called by muse, mutect2
- SP6 | c.192G>C p.S64= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV60618222, COSV60618347; called by muse, mutect2, varscan2
- STEAP4 | c.1047G>C p.V349= | Silent (SNP) | VAF 36/187 reads (19%) | catalogued as COSV57330162; called by muse, mutect2, varscan2
- TMOD1 | c.87C>A p.T29= | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as COSV52249308; called by muse, varscan2
- TRPV6 | c.951C>G p.L317= | Silent (SNP) | VAF 34/147 reads (23%) | catalogued as rs1362165822, COSV63892344; called by muse, mutect2, varscan2
- TRRAP | c.3507G>A p.E1169= | Silent (SNP) | VAF 75/141 reads (53%) | catalogued as COSV62847663; called by muse, mutect2, varscan2
- ZNF714 | c.210G>C p.V70= | Silent (SNP) | VAF 87/196 reads (44%) | catalogued as COSV52510240, COSV52513157; called by muse, mutect2, varscan2
- MIR409 | n.38C>G | RNA (SNP) | VAF 4/16 reads (25%) | called by muse, varscan2
